Somatic mutation profile of tumor specimen MP2PRT-PASUXJ-TMP1-A (aliquot MP2PRT-PASUXJ-TMP1-A-1-0-D-A81O-36) from MP2PRT case MP2PRT-PASUXJ, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Dead; Primary diagnosis: Leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 7.6 years (2,758 days).
Specimen MP2PRT-PASUXJ-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 02315eba-8ed3-4429-95d0-5a99eb2014f4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PASUXJ-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PASUXJ-NB1-A-1-0-D-A81O-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/097de177-6344-4384-a109-beee9d8afc29

The open-access MAF lists 12 somatic variants for this specimen: 6 protein-altering or splice-affecting, 5 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 5, Missense Mutation 5, Frame Shift Del 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AFDN | c.3812G>A p.R1271H | Missense Mutation (SNP) | VAF 82/260 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.584); catalogued as rs151265223; called by muse, mutect2, varscan2
- CRTAC1 | c.1003G>A p.A335T | Missense Mutation (SNP) | VAF 122/319 reads (38%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.987); catalogued as rs145731794; called by muse, mutect2, varscan2
- P3H2 | c.1808G>A p.R603Q | Missense Mutation (SNP) | VAF 106/254 reads (42%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.934); catalogued as rs374266006; called by muse, mutect2, varscan2
- POLG2 | c.109A>G p.S37G | Missense Mutation (SNP) | VAF 198/614 reads (32%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as rs1460188330; called by muse, mutect2, varscan2
- FBXO11 | c.995_998del p.F332Wfs*12 (on ENST00000403359 / NM_001190274.2; = p.F248Wfs*12 on NM_025133.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 26/166 reads (16%) | called by pindel*, varscan2
- ZAN | c.5506A>G p.R1836G | Missense Mutation (SNP) | VAF 219/650 reads (34%) | SIFT tolerated (0.47); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CNTN3 | c.435C>A p.G145= | Silent (SNP) | VAF 95/260 reads (37%) | called by muse, mutect2, varscan2
- LRRC4C | c.883C>A p.R295= | Silent (SNP) | VAF 114/382 reads (30%) | catalogued as rs747329999, COSV53438355; called by muse, mutect2, varscan2
- PTK6 | c.576G>A p.T192= | Silent (SNP) | VAF 88/615 reads (14%) | catalogued as rs768928217, COSV99420777; called by muse, mutect2, varscan2
- SPSB4 | c.393G>A p.A131= | Silent (SNP) | VAF 286/679 reads (42%) | catalogued as COSV100141609; called by muse, mutect2, varscan2
- ZNF536 | c.1662C>T p.N554= | Silent (SNP) | VAF 43/396 reads (11%) | catalogued as rs1456977194, COSV62823736, COSV62826132; called by muse, mutect2, varscan2
- IGLV4-60 | chr22:22162681 ins AGC | 3'Flank (INS) | VAF 72/182 reads (40%) | called by mutect2, pindel, varscan2
